Somatic mutation profile of tumor specimen MMRF_1650_1_BM_CD138pos (aliquot MMRF_1650_1_BM_CD138pos_T1_KBS5U_L06438) from MMRF case MMRF_1650, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.9 years (30,292 days).
Specimen MMRF_1650_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e1597be-0e94-4a06-8501-91ac0adaa9fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1650_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1650_1_PB_Whole_C2_KBS5U_L06500; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb6bcacf-ee31-4b6f-98ca-f92d898cba69

The open-access MAF lists 139 somatic variants for this specimen: 58 protein-altering or splice-affecting, 16 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, 3'UTR 43, Silent 16, Intron 14, 5'UTR 4, Nonsense Mutation 3, Splice Region 2, Splice Site 2, 3'Flank 2, Translation Start Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 18/152 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 91/330 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGAP2 | c.3017C>T p.T1006M (on ENST00000547588 / NM_001122772.2; = p.T650M on NM_014770.4) | Missense Mutation (SNP) | VAF 114/215 reads (53%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs768766650; called by muse, mutect2, varscan2
- ALK | c.4691C>T p.A1564V | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV101202111; called by muse, mutect2, varscan2
- CDK11A | c.365G>A p.R122Q (on ENST00000378633 / NM_001313896.2; = p.R132Q on NM_024011.4) | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.52); catalogued as rs750242434, COSV100651779; called by muse, mutect2, varscan2
- COL6A6 | c.4627G>A p.G1543R | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376262924; called by muse, varscan2
- CSHL1 | c.471+1G>C p.X157_splice (on ENST00000309894 / NM_022581.3; = p.X63_splice on NM_001318.4) | Splice Site (SNP) | VAF 6/70 reads (9%) | catalogued as COSV51989942; called by muse, mutect2
- EGF | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54484797; called by muse, mutect2, varscan2
- FAM53A | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 10/178 reads (6%) | catalogued as COSV57402495; called by muse, mutect2
- GOLGB1 | c.8827C>A p.L2943I | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100510461; called by muse, mutect2, varscan2
- IGKV2-30 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs750905502; called by mutect2, varscan2
- IGLV3-1 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as rs528877557; called by muse, varscan2
- IGLV3-1 | c.136T>A p.L46M | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs374795971; called by muse, varscan2
- IGLV3-1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs368495152; called by muse, varscan2
- MBTPS1 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs369349224; called by muse, mutect2, varscan2
- MMP14 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs971426762; called by muse, mutect2, varscan2
- MTCL1 | c.3479G>A p.R1160Q (on ENST00000306329 / NM_001378206.1; = p.R841Q on NM_015210.4) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs376928119; called by muse, mutect2, varscan2
- NCAPG2 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 55/97 reads (57%) | catalogued as COSV51987526; called by muse, mutect2, varscan2
- NOX5 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.143); catalogued as COSV52988171; called by muse, mutect2
- PIK3C2G | c.3542A>G p.N1181S (on ENST00000676171; = p.N1140S on NM_004570.5) | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs1222808761; called by muse, mutect2, varscan2
- PPP1R21 | c.761A>G p.D254G | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs765597385; called by muse, mutect2, varscan2
- SEC14L5 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs771138868; called by muse, mutect2
- SMURF1 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs182340234; called by muse, mutect2, varscan2
- TMEM132B | c.2645A>G p.N882S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs200623837; called by muse, mutect2, varscan2
- ZAN | c.4153A>G p.M1385V | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV100769464; called by muse, mutect2, varscan2
- ZNF132 | c.1994G>A p.S665N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1360384466; called by muse, mutect2, varscan2
- ACTN1 | c.7C>A p.H3N | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD13B | c.1178T>C p.M393T | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ARHGAP39 | c.209G>T p.W70L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ASTN2 | c.3419G>C p.G1140A (on ENST00000313400 / NM_001365069.1; = p.G1089A on NM_014010.5) | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2
- C14orf39 | c.1429A>T p.S477C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); called by muse, mutect2
- CAMK2G | c.1176G>T p.E392D (on ENST00000423381 / NM_001367518.1; = p.E358D on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDCA2 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CDH8 | c.284A>T p.K95I | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CSMD1 | c.10183C>A p.P3395T (on ENST00000520002; = p.P3394T on NM_033225.6) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- EGR4 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM117A | c.942A>T p.E314D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FUBP1 | c.473+2T>A p.X158_splice | Splice Site (SNP) | VAF 15/26 reads (58%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, varscan2
- IGHV2-70D | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, varscan2
- IL17RE | c.1058G>A p.C353Y | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KCNH4 | c.2510C>T p.T837I | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MTF2 | c.673T>C p.W225R | Missense Mutation (SNP) | VAF 51/108 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MYL10 | c.582G>C p.E194D | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); called by muse, mutect2
- OR1D5 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PADI3 | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PDZRN3 | c.972C>G p.F324L | Missense Mutation (SNP) | VAF 95/198 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RANBP10 | c.1689C>G p.I563M | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RO60 | c.427A>T p.M143L | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCP2 | c.588G>A p.P196= | Splice Region (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2
- SLCO1C1 | c.1360G>T p.G454* | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- SNCAIP | c.800A>T p.H267L | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOWAHC | c.713del p.G238Afs*25 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- TMEM132C | c.2288A>T p.E763V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TMEM176A | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- TNFAIP8 | c.-66C>T | Splice Region (SNP) | VAF 65/130 reads (50%) | called by muse, mutect2, varscan2
- TP53BP2 | c.820A>G p.K274E (on ENST00000343537 / NM_001031685.3; = p.K145E on NM_005426.2) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TPO | c.1980G>C p.Q660H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C4orf54 | c.1128T>C p.S376= | Silent (SNP) | VAF 41/167 reads (25%) | called by muse, mutect2, varscan2
- EGFR | c.2382C>A p.P794= | Silent (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2
- GFPT2 | c.1848C>T p.R616= | Silent (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- GINS2 | c.423A>G p.A141= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- H2BC3 | c.261C>A p.R87= | Silent (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- IGHV2-70D | c.303T>C p.L101= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1421187044; called by muse, varscan2
- IGHV2-70D | c.219T>C p.D73= | Silent (SNP) | VAF 22/53 reads (42%) | called by muse, varscan2
- IGKJ5 | c.9C>T p.T3= | Silent (SNP) | VAF 76/101 reads (75%) | catalogued as rs375348000; called by muse, varscan2
- IGKJ5 | c.6C>T p.I2= | Silent (SNP) | VAF 76/101 reads (75%) | catalogued as rs367938025; called by muse, varscan2
- JADE2 | c.2193A>T p.P731= | Silent (SNP) | VAF 57/120 reads (48%) | called by muse, mutect2, varscan2
- KLK15 | c.387G>A p.T129= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV56826959; called by muse, mutect2, varscan2
- PAX9 | c.126C>A p.I42= | Silent (SNP) | VAF 83/161 reads (52%) | called by muse, mutect2, varscan2
- RNF217 | c.405C>T p.P135= | Silent (SNP) | VAF 7/150 reads (5%) | called by muse, mutect2
- SZT2 | c.9213C>T p.L3071= (on ENST00000634258 / NM_001365999.1; = p.L3014= on NM_015284.4) | Silent (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- TBC1D9 | c.1968C>T p.Y656= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs754059861; called by muse, mutect2, varscan2
- ZNF274 | c.1887C>T p.T629= (on ENST00000610905; = p.T524= on NM_016324.3) | Silent (SNP) | VAF 81/171 reads (47%) | catalogued as rs1227916540, COSV58766601; called by muse, mutect2, varscan2
- AP001122.1 | n.630T>C | RNA (SNP) | VAF 70/154 reads (45%) | called by muse, mutect2, varscan2
- AP1S3 | c.430-5481G>A | Intron (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2
- APOL4 | c.44+116A>C | Intron (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- BAZ2A | c.737-66dup | Intron (INS) | VAF 6/78 reads (8%) | called by mutect2, pindel
- BSG | c.655+85C>G | Intron (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- C5orf15 | c.*616_*641del | 3'UTR (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- CAPN13 | c.*15C>A | 3'UTR (SNP) | VAF 13/142 reads (9%) | catalogued as rs1466017667; called by muse, mutect2
- CCDC68 | chr18:54902793 C>T | 3'Flank (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- CDK6 | c.*852T>A | 3'UTR (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- CHPF2 | c.-1454G>T | 5'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- CLCA2 | c.*878C>T | 3'UTR (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- CLRN1 | c.*4G>T | 3'UTR (SNP) | VAF 94/208 reads (45%) | called by muse, mutect2, varscan2
- CNKSR3 | c.*357G>A | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- CNOT6L | c.*6333C>A | 3'UTR (SNP) | VAF 34/77 reads (44%) | called by muse, mutect2, varscan2
- COL1A2 | c.2349+11A>G | Intron (SNP) | VAF 9/158 reads (6%) | called by muse, mutect2
- CSNK1A1 | c.*1864G>T | 3'UTR (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- CSPG5 | c.*126G>A | 3'UTR (SNP) | VAF 23/176 reads (13%) | called by muse, mutect2, varscan2
- CTSL | c.127-49T>C | Intron (SNP) | VAF 12/76 reads (16%) | catalogued as rs755907969; called by muse, mutect2, varscan2
- CYB5A | c.*323T>C | 3'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, varscan2
- DENND1B | c.*1729C>T | 3'UTR (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- DNAJC21 | c.*1399T>G | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- DNAJC24 | c.*571A>T | 3'UTR (SNP) | VAF 21/37 reads (57%) | called by muse, mutect2, varscan2
- ENDOD1 | c.*339A>G | 3'UTR (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- EPHA5 | c.*1053G>T | 3'UTR (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2, varscan2
- GLP2R | c.1056+4239C>T | Intron (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- HK2 | c.*386C>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | catalogued as rs1248323962; called by muse, mutect2
- HTR2A | c.-572G>T | 5'UTR (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2
- IGHV1-69D | c.-37T>A | 5'UTR (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- IL17D | c.*533T>G | 3'UTR (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- ISY1 | c.*1775T>G | 3'UTR (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- LRRC49 | c.1169+54G>A | Intron (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- MMP16 | c.*3959G>T | 3'UTR (SNP) | VAF 33/71 reads (46%) | catalogued as rs901055894; called by muse, mutect2, varscan2
- MRPL19 | c.*201C>A | 3'UTR (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- MTPN | c.*2117C>G | 3'UTR (SNP) | VAF 110/210 reads (52%) | called by muse, mutect2, varscan2
- MYO1E | c.-21G>C | 5'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- NCAM2 | c.*3217T>A | 3'UTR (SNP) | VAF 19/29 reads (66%) | called by muse, mutect2, varscan2
- NFX1 | c.*745T>C | 3'UTR (SNP) | VAF 15/71 reads (21%) | catalogued as rs997774939; called by muse, mutect2, varscan2
- NPC1L1 | c.*504G>A | 3'UTR (SNP) | VAF 11/97 reads (11%) | catalogued as rs533932206; called by muse, mutect2, varscan2
- PAMR1 | c.*414A>T | 3'UTR (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- PANK1 | c.*698G>A | 3'UTR (SNP) | VAF 59/127 reads (46%) | catalogued as rs1163703022; called by muse, mutect2, varscan2
- PCDH9 | c.*778T>G | 3'UTR (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- PDIA6 | c.19+2331A>T | Intron (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- PDXK | c.*4631C>A | 3'UTR (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- PID1 | chr2:229024846 del TTGA | 3'Flank (DEL) | VAF 22/48 reads (46%) | called by mutect2, pindel, varscan2
- PPP3R2 | c.*2653T>C | 3'UTR (SNP) | VAF 52/98 reads (53%) | called by muse, mutect2, varscan2
- PUDP | c.*1268A>G | 3'UTR (SNP) | VAF 41/42 reads (98%) | called by muse, mutect2, varscan2
- RAB2A | c.*2058T>C | 3'UTR (SNP) | VAF 29/60 reads (48%) | catalogued as rs1365117187; called by muse, mutect2, varscan2
- RNF121 | c.*324T>G | 3'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- RNF217 | c.*8105T>C | 3'UTR (SNP) | VAF 8/111 reads (7%) | catalogued as rs1459199852; called by muse, mutect2
- SARNP | c.406+78A>G | Intron (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- SEC62 | c.*4360T>A | 3'UTR (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- SESN1 | c.*254C>T | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- SGCD | c.*4597G>A | 3'UTR (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SLC6A16 | c.1941+88T>C | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.*3195C>T | 3'UTR (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-18533T>A | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- SNORD115-2 | chr15:25170597 C>T | 5'Flank (SNP) | VAF 8/23 reads (35%) | catalogued as rs941139962; called by muse, mutect2
- SOX1 | c.*1569G>A | 3'UTR (SNP) | VAF 24/68 reads (35%) | called by mutect2, varscan2
- ST8SIA6 | c.*736G>A | 3'UTR (SNP) | VAF 27/60 reads (45%) | catalogued as rs1208688856; called by muse, mutect2, varscan2
- SYNDIG1 | c.*820C>T | 3'UTR (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- TBX18 | c.*261G>A | 3'UTR (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- TMEM132C | c.85+26616dup | Intron (INS) | VAF 11/131 reads (8%) | called by mutect2, pindel
- TTC22 | c.1020+886C>T | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- WWC2 | c.*1936T>A | 3'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- ZNF135 | c.*1138G>A | 3'UTR (SNP) | VAF 20/34 reads (59%) | catalogued as rs527279005, COSV100536669; called by muse, mutect2
